Somatic mutation profile of tumor specimen 0DS291 from CCDI case PBCHFI, project CCDI-MCI: Molecular Characterization Initiative (MCI). Sex at birth: female; Primary diagnosis: Neoplasm, malignant; Tissue or organ of origin: Overlapping lesion of brain and central nervous system; Age at diagnosis: 13.1 years (4,783 days).
Specimen 0DS291: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) f74a091f-1dbb-49bf-a85f-848cdbf9eeb9.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 0DS29T (Peripheral Whole Blood; tissue type Normal); read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/ebcf950e-e85c-4ccf-80cd-c99feebd8550

The open-access MAF lists 26 somatic variants for this specimen: 13 protein-altering or splice-affecting, 8 silent, 5 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 13, Silent 8, Intron 3, 3'UTR 1, RNA 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- SMARCA4 | c.3575G>A p.R1192H | Missense Mutation (SNP) | VAF 46/628 reads (7%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV60785906, COSV60794673; called by muse, mutect2
- KCTD8 | c.1220G>A p.R407H | Missense Mutation (SNP) | VAF 74/1918 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); catalogued as rs756267175, COSV63585195, COSV63586274; called by muse, mutect2
- PGR | c.2164G>C p.G722R | Missense Mutation (SNP) | VAF 68/1394 reads (5%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.995); catalogued as CM984071; called by muse, mutect2
- ZNF831 | c.1067C>A p.P356Q | Missense Mutation (SNP) | VAF 26/390 reads (7%) | SIFT tolerated (0.22); PolyPhen benign (0.122); catalogued as COSV100925905; called by muse, mutect2
- ADGRB3 | c.3200A>C p.E1067A | Missense Mutation (SNP) | VAF 52/1220 reads (4%) | SIFT tolerated (0.7); PolyPhen possibly damaging (0.825); called by muse, mutect2
- AKAP8L | c.911A>G p.N304S | Missense Mutation (SNP) | VAF 48/305 reads (16%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.987); called by muse, mutect2, varscan2
- ANKHD1-EIF4EBP3 | c.697G>C p.E233Q | Missense Mutation (SNP) | VAF 299/1169 reads (26%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.614); called by muse, mutect2, varscan2
- HSPA2 | c.1291T>A p.F431I | Missense Mutation (SNP) | VAF 18/613 reads (3%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.63); called by muse, mutect2
- IGSF1 | c.1584G>C p.Q528H | Missense Mutation (SNP) | VAF 141/1391 reads (10%) | SIFT tolerated (0.08); PolyPhen benign (0.259); called by muse, mutect2, varscan2
- KCNQ2 | c.1240T>C p.S414P (on ENST00000359125 / NM_172107.4; = p.S404P on NM_004518.6) | Missense Mutation (SNP) | VAF 16/518 reads (3%) | SIFT tolerated (0.07); PolyPhen benign (0.014); called by muse, mutect2
- KCNQ5 | c.1231G>T p.G411W | Missense Mutation (SNP) | VAF 54/994 reads (5%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.497); called by muse, mutect2
- PHKG2 | c.524C>T p.S175F | Missense Mutation (SNP) | VAF 74/922 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); called by muse, mutect2
- RP1L1 | c.5971G>C p.G1991R | Missense Mutation (SNP) | VAF 16/464 reads (3%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.015); called by muse, mutect2
- ARHGEF18 | c.1611C>A p.A537= (on ENST00000359920 / NM_001130955.2; = p.A433= on NM_015318.4 and 1 other RefSeq transcript) | Silent (SNP) | VAF 20/449 reads (4%) | called by muse, mutect2
- ASIC5 | c.417C>A p.L139= | Silent (SNP) | VAF 74/2079 reads (4%) | called by muse, mutect2
- DSG1 | c.2511G>T p.V837= | Silent (SNP) | VAF 40/998 reads (4%) | called by muse, mutect2
- EMD | c.345G>A p.R115= | Silent (SNP) | VAF 28/843 reads (3%) | catalogued as COSV63962056; called by muse, mutect2
- MUC16 | c.5712G>A p.V1904= | Silent (SNP) | VAF 140/405 reads (35%) | catalogued as rs559101944; called by muse, mutect2
- NPTN | c.336G>T p.G112= | Silent (SNP) | VAF 50/1234 reads (4%) | called by muse, mutect2
- SERPINB8 | c.1124A>G p.*375= | Silent (SNP) | VAF 45/1002 reads (4%) | called by muse, mutect2
- XPO5 | c.2913C>T p.D971= | Silent (SNP) | VAF 72/568 reads (13%) | catalogued as rs774935973; called by muse, mutect2, varscan2
- AL033384.1 | n.302T>G | RNA (SNP) | VAF 22/456 reads (5%) | called by muse, mutect2
- C1RL | c.617-12T>G | Intron (SNP) | VAF 32/976 reads (3%) | called by muse, mutect2
- CSRP1 | c.*72A>G | 3'UTR (SNP) | VAF 52/244 reads (21%) | called by muse, mutect2, varscan2
- RET | c.3187+108A>T | Intron (SNP) | VAF 16/182 reads (9%) | called by muse, mutect2
- VCAN | c.4004-84T>C | Intron (SNP) | VAF 16/298 reads (5%) | catalogued as COSV99424984; called by muse, mutect2
